MMRF case MMRF_2549 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/61d762e7-60a8-486c-b8c2-ee4ba634088f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.8 years (23,652 days); ISS stage: III; Days to last known disease status: 695 days (1.9 years); Days to last follow up: 695 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 6 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 39 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 39 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 40 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 7 (ECOG 2): M Protein 2.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 369 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 34.5 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 6 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 30 g/L; Total Protein 9.2 g/dL; Glucose 6.33 mmol/L.
- Day 89 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 7.7 mmol/L.
- Day 173: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 6.77 mmol/L.
- Day 285 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Glucose 8.47 mmol/L.
- Day 369 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 1.33 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Glucose 10.8 mmol/L.
- Day 467 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 8.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 8.58 mmol/L.
- Day 558: Hemoglobin 6.01 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 642 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 6.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 1.36 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 5.28 mmol/L.
- Day 695: Serum Free Immunoglobulin Light Chain, Kappa 38.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 8.47 mmol/L.

Other clinical attributes
- Day 7: Weight: 121 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2549_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 7 days.
- Sample MMRF_2549_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 7 days.
